Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A66X, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A66X-01A (Primary Tumor).

TSS Patient ID:

OpenClinica ID:

Surgical Date:

Gross Description: Tumor is ill-margins, solid and firm, gray-white in cutting section with 10x8x6cm in size.

Microscopic Description: Tumor cells form the trabecular patterns connecting each other, or acinar or sheets patterns intervening in benign tissue. Tumor invades into fibrous stroma. The tumor cells retain apolygonal shape and have round vesicular nuclei with prominent nucleoli. The amount of cytoplasm are abundant and the cytoplasm is clear or basophilic. Nuclei are irregularly large and hyperchromatic with prominent nucleoli. Mitoses are present. Tumor is invasion of inflammatory cells and necrotic. Stroma is fibrous and hyaline.

Diagnosis Details: Hepatocellular carcinoma, clear cell type, poorly-differentiated

Comments:

Pw TSS, clear cell < 10%

Formatted Path Reports: LIVER TISSUE CHECKLIST

CCF Carcinoma, hepatocellular, NOS 817013

path Carcinoma, hepatocellular, clear cell type 817413

Specimen type: Wedge resection, lobectomy

Tumor size: 10 x 8 x 6 cm

*Site Liver C22.0
9605/16/13*

Focality: Not specified

Histologic type: Hepatocellular carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Hepatocellular carcinoma, clear cell type

Comments: None

Source: NCI Genomic Data Commons file 86920abb-6400-42f2-945b-9e18f9a8183a (TCGA-ED-A66X.F83A9A75-387A-4A66-9817-084A8E633E37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).